TCGA case TCGA-QR-A703 — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland; Tissue source site: National Institutes of Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a3b165e0-bec1-4dbc-b2d8-08fa21874cfa

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 23 years; Vital status: Alive.

Diagnoses (5)
1. Pheochromocytoma, NOS (the primary disease): ICD-O-3 morphology code: 8700/0; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 23.1 years (8,421 days); Year of diagnosis: 2008; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 1,167 days (3.2 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Synchronous primary of the adrenal gland (histology not recorded by GDC). Laterality: Left; Age at diagnosis: 22.6 years (8,237 days); Days to diagnosis: -184 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Head, face or neck, NOS; Classification of tumor: Synchronous primary; Age at diagnosis: 22.6 years (8,251 days); Days to diagnosis: -170 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Subsequent primary of the adrenal gland (histology not recorded by GDC). Age at diagnosis: 23.1 years (8,421 days); Prior treatment: Yes.
5. Subsequent primary of the autonomic nervous system (histology not recorded by GDC). Age at diagnosis: 23.3 years (8,527 days); Days to diagnosis: 106 days; Prior treatment: Yes.

Follow-up (2 entries)
- Day 0 (prior to diagnosis): History of tumor: Yes; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 1,167 days (3.2 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QR-A703-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-QR-A703-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QR-A703-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QR-A703-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: Yes; History pheo or para anatomic site: L adrenal pheo, right neck paraganglioma; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Pheochromocytoma; Ct scan preop results: Yes.
- New tumor event 1: New tumor event type: New Primary Tumor; New tumor event site other: Left Adrenal Pheochromocytoma; New tumor event diagnosis confirmed by: Pathology.
- New tumor event 2: New tumor event type: New Primary Tumor; New tumor event site other: Right Paraganglioma; New tumor event diagnosis confirmed by: Pathology.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy.
- Other malignancy form 2: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Neck; Other malignancy histological type: Paraganglioma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,167 days; disease-specific survival: no event (censored), 1,167 days; disease-free interval: no event (censored), 1,167 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 0 days.
